Somatic mutation profile of tumor specimen TCGA-E1-5311-01A (aliquot TCGA-E1-5311-01A-01D-1468-08) from TCGA case TCGA-E1-5311, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 31.0 years (11,332 days).
Specimen TCGA-E1-5311-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f37b444d-c232-40bb-9d60-75dfcb91aa24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5311-10A (Blood Derived Normal), aliquot TCGA-E1-5311-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1922c579-c29e-4c1f-b63e-f30a3c4125cb

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 57/86 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344635105, COSV50573658; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 73/168 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD11 | c.2759G>A p.R920K | Missense Mutation (SNP) | VAF 116/332 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773527879, COSV56363509; called by muse, mutect2, varscan2
- ECM1 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV60873677; called by muse, mutect2
- ELAPOR2 | c.2681T>G p.F894C (on ENST00000450689 / NM_001142749.3; = p.F727C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV51888131; called by muse, mutect2, varscan2
- FRAS1 | c.9191A>G p.N3064S | Missense Mutation (SNP) | VAF 109/257 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV53621705; called by muse, mutect2, varscan2
- HEATR5B | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51854560; called by muse, mutect2, varscan2
- IL15 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV56726221; called by muse, mutect2, varscan2
- MMS22L | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51522497; called by muse, mutect2
- NOTCH1 | c.1441G>C p.G481R | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448146225, COSV53033864, COSV53063079, COSV99487194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB1 | c.3459A>C p.K1153N | Missense Mutation (SNP) | VAF 172/425 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV62057174; called by muse, mutect2, varscan2
- SMC4 | c.2272G>C p.V758L | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV61005868; called by muse, mutect2, varscan2
- TCFL5 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs767486884, COSV53895877; called by muse, mutect2, varscan2
- PCDHGA3 | c.438G>A p.T146= | Silent (SNP) | VAF 78/147 reads (53%) | catalogued as COSV53909039; called by muse, mutect2, varscan2
- PPFIA1 | c.2646G>A p.T882= | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as rs1218307221, COSV54133244; called by muse, mutect2, varscan2
- SSH2 | c.783C>T p.I261= | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as COSV52174745; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792622 G>A | 3'Flank (SNP) | VAF 30/52 reads (58%) | catalogued as rs760127804; called by muse, mutect2, varscan2
